Gene-level copy-number profile of tumor specimen ALCH-AE6F-TTP1-A from ALCHEMIST case ALCH-AE6F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,206 days).
Specimen ALCH-AE6F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5ef4de0b-4d12-455d-88cc-719a521d9caa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE6F-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/8981c3ab-6c89-41b7-9d30-69c35aebda17

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 138; copy number 1: 6,287; copy number 2: 52,149; copy number 3: 290; copy number 4: 15; copy number 5: 5; copy number 6: 8; copy number 7: 5; copy number 10: 1; copy number 11: 1; copy number 12: 1; copy number 16: 2; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,137,017–1,361,777, 27 genes: LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10, TNFRSF18, TNFRSF4, SDF4, B3GALT6, C1QTNF12, AL162741.1, UBE2J2, LINC01786, SCNN1D, ACAP3, MIR6726, PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808, MXRA8.
- chr1:36,402,721–36,402,859, 1 gene: RNU4-27P.
- chr1:200,008,505–200,008,607, 1 gene: RNU6-716P.
- chr2:241,800,916–241,812,016, 2 genes (within-gene range 0–2): AC131097.1, AC131097.2.
- chr3:126,973,065–127,037,392, 2 genes: AC011199.1, PLXNA1.
- chr3:155,821,024–155,854,456, 1 gene: SLC33A1.
- chr5:17,647,712–17,670,571, 6 genes: AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22.
- chr6:29,672,483–29,681,155, 1 gene: ZFP57.
- chr6:49,499,923–49,561,907, 2 genes: GLYATL3, C6orf141.
- chr7:76,968,197–76,976,961, 2 genes: FDPSP7, AC114737.1.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr8:80,265,528–80,484,481, 4 genes (within-gene range 0–1): AC104212.3, AC034114.2, AC104212.2, AC104212.1.
- chr10:38,403,189–38,455,365, 3 genes (within-gene range 0–1): AL133216.2, RNU6-1118P, CICP9.
- chr10:43,341,786–43,341,910, 1 gene: RNU6ATAC11P.
- chr11:1,991,096–2,001,470, 5 genes: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr11:47,164,299–47,191,542, 5 genes (within-gene range 0–2): ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1.
- chr12:132,550,729–132,554,947, 1 gene (within-gene range 0–2): AC131212.3.
- chr14:49,570,984–49,629,890, 11 genes (within-gene range 0–2): RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, AL139099.2.
- chr14:102,501,676–102,555,826, 4 genes (within-gene range 0–2): RNU6-244P, ANKRD9, MIR4309, LINC02323.
- chr15:23,430,839–23,435,212, 1 gene: HERC2P6.
- chr16:1,064,093–1,148,754, 7 genes: SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8.
- chr16:1,156,976–1,160,176, 2 genes (within-gene range 0–1): AC120498.3, AC120498.1.
- chr16:15,125,242–15,154,564, 3 genes (within-gene range 0–2): PKD1P6, MIR6511B2, Y_RNA.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:80,960,766–80,961,713, 1 gene (within-gene range 0–2): AC127496.4.
- chr19:55,705,978–55,738,402, 4 genes (within-gene range 0–2): AC010525.2, AC008749.1, NLRP9, RN7SKP109.
- chr20:25,284,915–25,285,588, 1 gene (within-gene range 0–2): AL121772.3.
- chr20:62,463,497–62,570,764, 7 genes (within-gene range 0–2): GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2.
- chr20:63,939,829–63,956,985, 4 genes (within-gene range 0–2): UCKL1, MIR1914, MIR647, UCKL1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene, copy number 7: MIR5692C1.
- chr11:1,947,278–1,989,920, 2 genes, copy number 11–12: MRPL23, MRPL23-AS1.
- chr13:41,442,770–41,470,871, 2 genes, copy number 5: OR7E37P, RGCC.
- chr13:112,313,467–112,321,758, 1 gene, copy number 7: LINC01043.
- chr15:22,160,431–22,160,868, 1 gene, copy number 7: IGHV1OR15-1.
- chr16:10,718,633–10,725,296, 8 genes, copy number 6: MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24.
- chr19:7,037,748–7,058,640, 3 genes, copy number 5–16: MBD3L4, MBD3L2, MBD3L3.
- chr19:41,449,520–41,506,898, 2 genes, copy number 5: PCAT19, AC243960.2.
- chr21:43,414,483–43,479,534, 4 genes, copy number 7–19: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 3,481. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
